Somatic mutation profile of tumor specimen MMRF_2477_1_BM_CD138pos (aliquot MMRF_2477_1_BM_CD138pos_T1_KHS5U_L11085) from MMRF case MMRF_2477, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.4 years (22,414 days).
Specimen MMRF_2477_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0c7d755-6731-41b2-a421-f14cf757e558.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2477_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2477_1_PB_Whole_C2_KHS5U_L11086; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eeb577b8-11c7-4d62-8b22-b53d7bac25ee

The open-access MAF lists 133 somatic variants for this specimen: 50 protein-altering or splice-affecting, 17 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 39, Missense Mutation 39, Silent 17, Intron 15, RNA 5, 3'Flank 4, Splice Site 3, In Frame Del 3, Frame Shift Del 2, 5'Flank 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 105/225 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs147836461; called by muse, mutect2, varscan2
- ADARB2 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV67216870; called by muse, mutect2
- AMPH | c.1556G>A p.G519D | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV57760685; called by muse, mutect2, varscan2
- B3GALNT2 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV58357437; called by muse, mutect2, varscan2
- EGR1 | c.175_180del p.G59_S60del | In Frame Del (DEL) | VAF 44/118 reads (37%) | catalogued as rs1032087174; called by pindel, varscan2
- FCGR2C | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 129/129 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as COSV63435688; called by muse, mutect2, varscan2
- GAD2 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 90/204 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.375); catalogued as rs1294603687; called by muse, mutect2, varscan2
- H2BC10 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 204/446 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.739); catalogued as rs750192940, COSV100010410; called by muse, mutect2, varscan2
- IGHJ5 | c.29C>A p.T10N | Missense Mutation (SNP) | VAF 31/77 reads (40%) | PolyPhen possibly damaging (0.602); catalogued as rs376021301; called by muse, varscan2
- IGHV2-70 | c.181C>G p.P61A | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.211); catalogued as rs377540429; called by muse, varscan2
- IGHV2-70 | c.95A>C p.K32T | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs371469802; called by muse, varscan2
- IGLL5 | c.125T>C p.M42T | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs140298238; called by muse, varscan2
- KANK4 | c.2686G>C p.G896R | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58091923; called by muse, mutect2, varscan2
- KCNN1 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.418); catalogued as COSV55837064; called by muse, mutect2, varscan2
- MXRA5 | c.6415G>A p.V2139M | Missense Mutation (SNP) | VAF 27/27 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776090640, COSV99476435; called by muse, mutect2, varscan2
- PLEKHA5 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV54708702; called by muse, mutect2, varscan2
- TRO | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 68/89 reads (76%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs748221975; called by muse, mutect2, varscan2
- TTI1 | c.3088G>A p.V1030I | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as rs373454060; called by muse, mutect2, varscan2
- ZNF174 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV51902804; called by muse, mutect2, varscan2
- ABCA5 | c.2266T>A p.F756I | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCB6 | c.1048_1056del p.F350_H352del | In Frame Del (DEL) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- C2orf42 | c.1353+2T>C p.X451_splice | Splice Site (SNP) | VAF 13/167 reads (8%) | called by muse, mutect2
- CHD9 | c.8150G>A p.G2717E (on ENST00000398510 / NM_001382353.1; = p.G2701E on NM_025134.7) | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCX | c.1025G>T p.S342I (on ENST00000636035 / NM_001195553.2; = p.S337I on NM_000555.3) | Missense Mutation (SNP) | VAF 38/38 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DHX58 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FOXI1 | c.422A>T p.D141V | Missense Mutation (SNP) | VAF 201/427 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- IGSF10 | c.2121G>T p.E707D | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- IL31RA | c.1624T>G p.F542V | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC9 | c.2593_2595del p.S865del | In Frame Del (DEL) | VAF 45/101 reads (45%) | called by mutect2, pindel, varscan2
- MYO1G | c.2428C>T p.P810S | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OAF | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR4D1 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PGM1 | c.418C>G p.P140A | Missense Mutation (SNP) | VAF 77/159 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- PIGG | c.1614+7A>G | Splice Region (SNP) | VAF 199/405 reads (49%) | called by muse, mutect2, varscan2
- PLCH1 | c.2584-2A>G p.X862_splice | Splice Site (SNP) | VAF 9/106 reads (8%) | called by muse, mutect2
- PREX2 | c.2705G>C p.S902T | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- RBBP5 | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- SETMAR | c.119del p.G40Afs*19 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
- SRGAP3 | c.2343G>A p.W781* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- TDRD1 | c.870A>T p.E290D | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- TMC8 | c.2094_2095insA p.A699Sfs*112 | Frame Shift Ins (INS) | VAF 21/56 reads (38%) | called by mutect2, pindel, varscan2
- TRPM5 | c.906+1G>T p.X302_splice | Splice Site (SNP) | VAF 50/119 reads (42%) | called by muse, mutect2, varscan2
- TTLL6 | c.2303A>T p.N768I (on ENST00000393382 / NM_001130918.3; = p.N461I on NM_173623.3) | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- UEVLD | c.1315T>C p.S439P | Missense Mutation (SNP) | VAF 114/326 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- VANGL2 | c.1206G>A p.M402I | Missense Mutation (SNP) | VAF 216/322 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- YARS2 | c.712T>C p.C238R | Missense Mutation (SNP) | VAF 100/177 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZMYND19 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 96/212 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF676 | c.1845del p.H615Qfs*? (on ENST00000650058; = p.H583Qfs*121 on NM_001001411.3) | Frame Shift Del (DEL) | VAF 32/81 reads (40%) | called by mutect2, pindel*, varscan2
- ADCY8 | c.2358C>T p.N786= | Silent (SNP) | VAF 236/303 reads (78%) | catalogued as rs370325893; called by muse, mutect2, varscan2
- DNAAF2 | c.831C>T p.S277= | Silent (SNP) | VAF 91/175 reads (52%) | catalogued as COSV53569308; called by muse, mutect2, varscan2
- EGR1 | c.180C>T p.S60= | Silent (SNP) | VAF 54/119 reads (45%) | catalogued as rs543007172; called by muse, varscan2
- FGFR2 | c.120C>T p.T40= | Silent (SNP) | VAF 96/185 reads (52%) | called by muse, mutect2, varscan2
- GALNT13 | c.1362T>G p.G454= | Silent (SNP) | VAF 80/168 reads (48%) | called by muse, mutect2, varscan2
- KLF2 | c.186G>A p.P62= | Silent (SNP) | VAF 4/59 reads (7%) | called by muse, mutect2
- MAN2C1 | c.186G>T p.R62= | Silent (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- MINDY4B | c.1182T>C p.F394= | Silent (SNP) | VAF 99/219 reads (45%) | called by muse, mutect2, varscan2
- PDLIM3 | c.132C>A p.P44= (on ENST00000284770 / NM_001257963.1; = p.P123= on NM_014476.6) | Silent (SNP) | VAF 118/191 reads (62%) | called by muse, mutect2, varscan2
- PLXNB3 | c.5040C>T p.R1680= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs1557064793; called by muse, mutect2, varscan2
- ROR1 | c.1257T>G p.A419= | Silent (SNP) | VAF 93/183 reads (51%) | called by muse, mutect2, varscan2
- SI | c.681A>G p.L227= | Silent (SNP) | VAF 15/23 reads (65%) | called by muse, mutect2
- SIGLEC1 | c.3156G>A p.L1052= | Silent (SNP) | VAF 84/195 reads (43%) | called by muse, mutect2, varscan2
- SLC2A9 | c.1251G>T p.V417= | Silent (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- SPANXN4 | c.192A>C p.S64= | Silent (SNP) | VAF 105/105 reads (100%) | called by muse, mutect2, varscan2
- TSPAN10 | c.951C>T p.C317= (on ENST00000574882 / NM_001290212.1; = p.C279= on NM_031945.4) | Silent (SNP) | VAF 55/80 reads (69%) | called by muse, mutect2, varscan2
- ZNF451 | c.2277G>A p.S759= | Silent (SNP) | VAF 82/183 reads (45%) | catalogued as rs768269747, COSV100675137; called by muse, mutect2, varscan2
- AC009533.1 | n.645T>G | RNA (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- AC083864.1 | n.590G>A | RNA (SNP) | VAF 39/61 reads (64%) | called by muse, mutect2, varscan2
- ADAP1 | c.*821C>T | 3'UTR (SNP) | VAF 103/195 reads (53%) | catalogued as rs1465711813; called by muse, mutect2, varscan2
- ADAR | c.*865T>G | 3'UTR (SNP) | VAF 25/94 reads (27%) | called by muse, mutect2, varscan2
- AMER2 | chr13:25166676 C>T | 3'Flank (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- AP000769.5 | chr11:65499437 C>T | 5'Flank (SNP) | VAF 38/72 reads (53%) | catalogued as rs1187710118; called by muse, mutect2, varscan2
- ASTN2 | c.2807-35433T>C | Intron (SNP) | VAF 47/77 reads (61%) | catalogued as rs1264230299; called by muse, mutect2, varscan2
- C20orf85 | c.*143G>T | 3'UTR (SNP) | VAF 44/73 reads (60%) | called by muse, mutect2, varscan2
- C7orf25 | c.*351G>T | 3'UTR (SNP) | VAF 24/43 reads (56%) | called by muse, mutect2, varscan2
- CACNA1S | c.*99C>T | 3'UTR (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- CAND1 | c.*6342T>C | 3'UTR (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- CASZ1 | c.*116G>A | 3'UTR (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- CBX2 | c.288+154C>G | Intron (SNP) | VAF 86/194 reads (44%) | called by muse, mutect2, varscan2
- CCDC85A | c.*880C>G | 3'UTR (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- CDH1 | c.*1611C>G | 3'UTR (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2, varscan2
- CLDN16 | c.*1360T>A | 3'UTR (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- DCAF4L1 | c.*785dup | 3'UTR (INS) | VAF 42/100 reads (42%) | called by mutect2, pindel, varscan2
- DDX12P | n.518T>G | RNA (SNP) | VAF 16/53 reads (30%) | called by mutect2, varscan2
- DNAJB11 | c.-143G>C | 5'UTR (SNP) | VAF 43/71 reads (61%) | called by muse, mutect2, varscan2
- EBAG9 | c.429+852T>G | Intron (SNP) | VAF 25/48 reads (52%) | catalogued as rs971111727; called by muse, mutect2, varscan2
- ERBB2 | c.*16C>T | 3'UTR (SNP) | VAF 64/136 reads (47%) | catalogued as rs1198824920, COSV99506232; called by muse, mutect2, varscan2
- F3 | c.*339dup | 3'UTR (INS) | VAF 28/64 reads (44%) | catalogued as rs1225918420; called by mutect2, pindel, varscan2
- FAM221B | c.743-1504C>T | Intron (SNP) | VAF 40/98 reads (41%) | called by muse, mutect2, varscan2
- FKTN | c.*4531C>T | 3'UTR (SNP) | VAF 56/105 reads (53%) | called by muse, mutect2, varscan2
- FNDC10 | c.*604A>G | 3'UTR (SNP) | VAF 59/104 reads (57%) | catalogued as rs953985632; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.383-2374T>G | Intron (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- GLP2R | c.1056+4045G>A | Intron (SNP) | VAF 76/146 reads (52%) | catalogued as rs1434448290; called by muse, mutect2, varscan2
- GLRB | c.*975T>A | 3'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- H6PD | c.*4956G>A | 3'UTR (SNP) | VAF 88/172 reads (51%) | called by muse, mutect2, varscan2
- HHIP | c.*3312G>A | 3'UTR (SNP) | VAF 36/78 reads (46%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+3250A>G | Intron (SNP) | VAF 35/133 reads (26%) | catalogued as rs1199488374; called by muse, mutect2, varscan2
- ITGA2 | c.*104G>A | 3'UTR (SNP) | VAF 43/96 reads (45%) | catalogued as COSV56859682; called by muse, mutect2, varscan2
- JAGN1 | c.*323A>T | 3'UTR (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- KRT77 | c.*896T>C | 3'UTR (SNP) | VAF 85/159 reads (53%) | called by muse, mutect2, varscan2
- LRCH2 | c.*900T>G | 3'UTR (SNP) | VAF 21/21 reads (100%) | called by muse, mutect2, varscan2
- LTB | c.162+105_162+120del | Intron (DEL) | VAF 18/58 reads (31%) | called by mutect2, varscan2
- MACROD2 | chr20:13995615 G>C | 5'Flank (SNP) | VAF 14/43 reads (33%) | called by muse, varscan2
- MCM3 | c.*388G>A | 3'UTR (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- MSTO1 | c.*297T>A | 3'UTR (SNP) | VAF 23/447 reads (5%) | called by muse, mutect2
- NCOR2 | c.6959-1520A>C | Intron (SNP) | VAF 70/197 reads (36%) | called by muse, mutect2, varscan2
- NRXN2 | c.3403+5103C>T | Intron (SNP) | VAF 20/51 reads (39%) | catalogued as rs1304379191; called by muse, mutect2, varscan2
- NT5E | c.1360+427G>A | Intron (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- PBX1 | c.998-48G>A | Intron (SNP) | VAF 123/187 reads (66%) | called by muse, mutect2, varscan2
- PCDH18 | c.*728C>T | 3'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- POMGNT1 | c.1539+12G>A | Intron (SNP) | VAF 75/166 reads (45%) | called by muse, mutect2, varscan2
- PTPRB | chr12:70517509 C>T | 3'Flank (SNP) | VAF 60/124 reads (48%) | catalogued as rs899865546; called by muse, mutect2, varscan2
- PXDN | c.1408+35C>T | Intron (SNP) | VAF 27/45 reads (60%) | catalogued as rs771917710; called by muse, mutect2, varscan2
- RALGPS2 | c.*1269A>G | 3'UTR (SNP) | VAF 76/131 reads (58%) | called by muse, mutect2, varscan2
- RGS3 | c.*568G>A | 3'UTR (SNP) | VAF 106/202 reads (52%) | called by muse, mutect2, varscan2
- SEMA3E | c.*1707T>C | 3'UTR (SNP) | VAF 57/108 reads (53%) | called by muse, mutect2, varscan2
- SFRP1 | c.*1523T>C | 3'UTR (SNP) | VAF 56/191 reads (29%) | called by muse, mutect2, varscan2
- SLC16A7 | c.*786A>G | 3'UTR (SNP) | VAF 35/88 reads (40%) | called by muse, mutect2, varscan2
- SLC1A2 | c.*4702T>G | 3'UTR (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143624091 G>C | 3'Flank (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- SMAD2 | c.*6336T>A | 3'UTR (SNP) | VAF 73/146 reads (50%) | called by muse, mutect2, varscan2
- SNX18 | chr5:54544409 ins A | 3'Flank (INS) | VAF 32/75 reads (43%) | catalogued as rs70986695; called by mutect2, varscan2
- SORCS3 | c.*1643T>A | 3'UTR (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- TNFRSF11A | c.*643C>A | 3'UTR (SNP) | VAF 49/96 reads (51%) | called by muse, varscan2
- TRIM32 | c.*51T>G | 3'UTR (SNP) | VAF 71/154 reads (46%) | called by muse, mutect2, varscan2
- TSBP1-AS1 | n.67A>G | RNA (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- TSLP | c.*18C>G | 3'UTR (SNP) | VAF 108/209 reads (52%) | catalogued as rs377757437; called by muse, mutect2, varscan2
- UST | c.*2387G>T | 3'UTR (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2, varscan2
- ZNF100 | c.*46del | 3'UTR (DEL) | VAF 24/82 reads (29%) | called by pindel, varscan2
- ZNF725P | n.946A>C | RNA (SNP) | VAF 22/37 reads (59%) | called by muse, mutect2, varscan2
- ZNF813 | c.-73-3712C>A | Intron (SNP) | VAF 31/155 reads (20%) | called by muse, mutect2, varscan2
- ZXDC | c.*179T>G | 3'UTR (SNP) | VAF 41/103 reads (40%) | called by muse, mutect2, varscan2
